CPTAC case GTEX-P44H-0011-R10A-SM-HAKXX — Brain (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/20bda057-349d-46f7-aeb5-ccf011cb107f

Demographics
Sex at birth: male; Race: white; Age at index: 43 years; Vital status: Dead; Days to death: 0 days.

Exposures
- Alcohol history: Yes.

Biospecimens (1 sample)
- Sample PT-P44H-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2.
